Somatic mutation profile of tumor specimen TCGA-EE-A185-06A (aliquot TCGA-EE-A185-06A-11D-A196-08) from TCGA case TCGA-EE-A185, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.5 years (20,255 days).
Specimen TCGA-EE-A185-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a41330e-3769-4780-91e1-17a16429e3b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A185-10A (Blood Derived Normal), aliquot TCGA-EE-A185-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f23e90d9-8c7c-4f5e-9b05-9671869586e5

The open-access MAF lists 226 somatic variants for this specimen: 154 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 66, Nonsense Mutation 13, RNA 3, Intron 3, Frame Shift Del 3, Splice Region 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 80/96 reads (83%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 97/108 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RIT1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.646); catalogued as rs869025192, COSV100851175, COSV64170945; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK19 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs267600971, COSV61712753; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51621062; called by muse, mutect2, varscan2
- ABCA13 | c.3492A>T p.L1164F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV70026426; called by muse, mutect2, varscan2
- ACE | c.3281G>A p.R1094K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52004309; called by muse, mutect2, varscan2
- ADAM28 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.084); catalogued as COSV56098516; called by muse, mutect2, varscan2
- ADARB1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV62342613, COSV62343666; called by muse, mutect2, varscan2
- AFM | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1033138160, COSV56919314; called by muse, mutect2, varscan2
- AKT2 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV60907832; called by muse, mutect2, varscan2
- AL592490.1 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425012; called by muse, mutect2, varscan2
- APAF1 | c.622C>T p.Q208* (on ENST00000551964 / NM_181861.2; = p.Q197* on NM_001160.3) | Nonsense Mutation (SNP) | VAF 51/102 reads (50%) | catalogued as COSV59662203; called by muse, mutect2, varscan2
- APTX | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs751301480, COSV58927839; called by muse, mutect2, varscan2
- ATP13A4 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV55066276, COSV55076321; called by muse, mutect2, varscan2
- CABP4 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs966008036, COSV56885213; called by muse, mutect2, varscan2
- CAMSAP2 | c.4144C>T p.Q1382* (on ENST00000236925 / NM_001297707.2; = p.Q1371* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV52667554; called by muse, mutect2, varscan2
- CAVIN2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV100414402, COSV58423531; called by muse, mutect2, varscan2
- CD300LD | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60083394; called by muse, mutect2, varscan2
- CDC42EP3 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54873562; called by muse, mutect2, varscan2
- CEP162 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV57618090; called by muse, mutect2, varscan2
- CNTN1 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV61637086; called by muse, mutect2, varscan2
- COL7A1 | c.8477C>G p.S2826C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as COSV56476120; called by muse, mutect2, varscan2
- COP1 | c.1874G>C p.W625S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58164143, COSV58164246; called by muse, varscan2
- CROCC | c.852C>T p.S284= | Splice Region (SNP) | VAF 52/104 reads (50%) | catalogued as rs753053196, COSV65010624, COSV65012365; called by muse, mutect2, varscan2
- DNAH3 | c.10018G>A p.E3340K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as rs184864743; called by muse, mutect2, varscan2
- DNAH5 | c.9617G>A p.G3206E | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209483, COSV99447926; called by muse, mutect2, varscan2
- DPRX | c.165A>G p.I55M | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV64949282; called by muse, mutect2, varscan2
- DYRK4 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV50538053; called by muse, mutect2, varscan2
- ELAVL2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV56356572; called by muse, mutect2, varscan2
- ELAVL3 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63645308; called by muse, mutect2, varscan2
- ERICH6 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV55799220; called by muse, mutect2, varscan2
- FAM184A | c.2168C>T p.T723M | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs372303662, COSV58853616; called by muse, mutect2, varscan2
- FAT4 | c.11462G>A p.R3821Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs142857910; called by muse, mutect2, varscan2
- FGF7 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51065635; called by muse, mutect2
- FGL2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV50380446; called by muse, mutect2, varscan2
- FNDC1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932660; called by muse, mutect2, varscan2
- GABRA3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV64796141; called by muse, mutect2, varscan2
- GBA2 | c.1249A>G p.I417V | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV62305401; called by muse, mutect2, varscan2
- GGA3 | c.727G>A p.G243R (on ENST00000537686 / NM_138619.4; = p.G210R on NM_014001.5) | Missense Mutation (SNP) | VAF 127/228 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs759824501; called by muse, mutect2, varscan2
- GP6 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV59976584; called by muse, mutect2, varscan2
- GPR45 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV51523057; called by muse, mutect2, varscan2
- HBD | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53082140, COSV99496475; called by muse, mutect2, varscan2
- HDAC11 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55472565; called by muse, mutect2, varscan2
- HERC5 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52037878; called by muse, mutect2, varscan2
- HRH1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV67955138; called by muse, mutect2, varscan2
- HSD3B2 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV65592713; called by muse, mutect2, varscan2
- HSD3B2 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 90/123 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65592719; called by muse, mutect2, varscan2
- HTR3C | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1553797478, COSV59174514; called by muse, mutect2, varscan2
- HYLS1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV54988965; called by muse, mutect2, varscan2
- IL1RAPL1 | c.191A>C p.Y64S | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56243516; called by muse, mutect2, varscan2
- IL27RA | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs372221939; called by muse, mutect2, varscan2
- IQUB | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV61237773; called by muse, mutect2, varscan2
- IRS1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59334268; called by muse, mutect2, varscan2
- IVNS1ABP | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 101/111 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV62250670; called by muse, mutect2, varscan2
- JCAD | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV64758367; called by muse, mutect2, varscan2
- KCNH3 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV57789893; called by muse, mutect2, varscan2
- KRTAP5-8 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.806); catalogued as rs747469393, COSV68324473; called by muse, mutect2, varscan2
- LCE1B | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 102/112 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63980120; called by muse, mutect2, varscan2
- LEXM | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs1338321927, COSV64022237; called by muse, mutect2, varscan2
- LILRB4 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54403911; called by muse, mutect2
- LMBRD1 | c.550C>T p.P184S (on ENST00000649011; = p.P162S on NM_018368.4) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV65296376; called by muse, mutect2, varscan2
- LNP1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV67346284; called by muse, mutect2, varscan2
- LRRC4C | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.981); catalogued as rs1450656731, COSV53419909, COSV99538496; called by muse, mutect2, varscan2
- LYPD6 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61939113; called by muse, mutect2, varscan2
- MARCO | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.488); catalogued as COSV59052545; called by muse, mutect2, varscan2
- MINDY4 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV54672026; called by muse, mutect2, varscan2
- MISP | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs45591331; called by muse, mutect2, varscan2
- MS4A1 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV61941801; called by muse, mutect2, varscan2
- MST1R | c.3500G>A p.G1167D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56565716; called by muse, mutect2, varscan2
- MUC16 | c.34483C>T p.P11495S | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV67451328; called by muse, mutect2, varscan2
- MUC16 | c.28927G>A p.E9643K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as COSV67451345; called by muse, mutect2
- MYH6 | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369275573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55683047, COSV55683465; called by muse, mutect2, varscan2
- NBR1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.576); catalogued as rs772134578, COSV57831174; called by muse, mutect2
- NDST4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.094); catalogued as COSV52107677; called by muse, mutect2, varscan2
- NRK | c.4388T>A p.I1463N | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54591475; called by muse, mutect2, varscan2
- NT5C1B | c.781C>T p.R261C (on ENST00000359846 / NM_001199086.2; = p.R201C on NM_033253.4) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV58394741; called by muse, mutect2, varscan2
- NTPCR | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV64052246; called by muse, mutect2, varscan2
- NYAP2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1309957389, COSV55998211; called by muse, mutect2, varscan2
- OR2AG1 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as COSV56625604; called by muse, mutect2, varscan2
- OR2T5 | c.168C>G p.D56E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100822190; called by mutect2, varscan2
- OR52J3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs146387387; called by muse, mutect2, varscan2
- OR5AK2 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58803969; called by muse, mutect2, varscan2
- ORAI3 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV52685679; called by muse, mutect2, varscan2
- ORC4 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV51572296; called by muse, mutect2, varscan2
- PACC1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV54786503, COSV54787276; called by muse, varscan2
- PAG1 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV55056069, COSV99597922; called by muse, mutect2, varscan2
- PAPPA2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 69/78 reads (88%) | catalogued as COSV62774494; called by muse, mutect2, varscan2
- PARM1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1389763301, COSV56650901; called by muse, mutect2, varscan2
- PCDH15 | c.2995A>T p.T999S | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.82); PolyPhen benign (0.015); catalogued as COSV57271846; called by muse, mutect2, varscan2
- PCDHA8 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs868934448, COSV65324070; called by muse, mutect2, varscan2
- PCDHB3 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as rs1294837469, COSV50565147; called by muse, mutect2, varscan2
- PCDHB6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs1194664955, COSV50691071; called by muse, mutect2, varscan2
- PIK3R5 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.282); catalogued as COSV52651304; called by muse, mutect2, varscan2
- PKDREJ | c.5077G>A p.E1693K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV53547099; called by muse, mutect2, varscan2
- PLCE1 | c.6686G>A p.G2229E | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156639637, COSV53340854; called by muse, mutect2, varscan2
- PLIN2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52802767; called by muse, mutect2, varscan2
- POLD3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.069); catalogued as COSV55242452; called by muse, mutect2, varscan2
- PPIB | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV55519683; called by muse, mutect2, varscan2
- PSG4 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV54932663; called by muse, mutect2, varscan2
- RAD18 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs775651620, COSV53749464; called by muse, mutect2, varscan2
- RIT1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as COSV64170938; called by muse, mutect2, varscan2
- RP1 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV55112157; called by muse, mutect2, varscan2
- RSPH1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as rs747819266, COSV52318261, COSV99370474; called by muse, mutect2, varscan2
- RTN2 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | catalogued as rs1256463947, COSV55592944; called by muse, mutect2
- RTN2 | c.917T>G p.V306G | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.081); catalogued as COSV99839260; called by muse, mutect2
- SCN10A | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV71860312; called by muse, mutect2, varscan2
- SDHAF4 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1227491369, COSV65085023; called by muse, mutect2, varscan2
- SEMA3A | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54863951, COSV99037512; called by muse, mutect2, varscan2
- SERPINB7 | c.782G>A p.W261* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs778253378, COSV60532901; called by muse, mutect2, varscan2
- SERPINB9 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66233065; called by muse, mutect2, varscan2
- SEZ6L | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV50659081; called by muse, mutect2, varscan2
- SI | c.3910G>A p.E1304K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52266105; called by muse, mutect2, varscan2
- SIDT2 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 167/415 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439026606, COSV54055770; called by muse, mutect2, varscan2
- SIGLEC7 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs577893614; called by muse, mutect2, varscan2
- SIGLEC7 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58318069; called by muse, mutect2, varscan2
- SLC10A2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55357554; called by muse, mutect2, varscan2
- SLC14A2 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV54907078; called by muse, mutect2, varscan2
- SLC22A14 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs1368676299, COSV56196792; called by muse, mutect2, varscan2
- SLC4A3 | c.2606G>A p.G869D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56092073; called by muse, mutect2, varscan2
- SMARCAL1 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs774633377, COSV61920201; called by muse, mutect2, varscan2
- SP140 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as COSV59447220; called by muse, mutect2, varscan2
- SPACA7 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs201127697; called by muse, mutect2, varscan2
- ST3GAL1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | PolyPhen benign (0.408); catalogued as COSV60610953; called by muse, mutect2, varscan2
- ST8SIA3 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 20/34 reads (59%) | PolyPhen probably damaging (1); catalogued as COSV100129587, COSV60653508; called by muse, mutect2
- TCF20 | c.4927C>A p.L1643I | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV59489030; called by muse, mutect2, varscan2
- TCF20 | c.4286C>T p.P1429L | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); catalogued as rs747582935, COSV59489040; called by muse, mutect2, varscan2
- THSD1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs554446714; called by muse, mutect2, varscan2
- TMEM50A | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV65486143; called by muse, mutect2, varscan2
- TMPRSS15 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV53036016; called by muse, mutect2, varscan2
- TRIM29 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs771869031, COSV59279371; called by muse, mutect2, varscan2
- TRPM6 | c.3268C>T p.R1090C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62504431; called by muse, mutect2, varscan2
- TSPEAR | c.304-1G>A p.X102_splice | Splice Site (SNP) | VAF 17/24 reads (71%) | catalogued as COSV59954475; called by muse, mutect2, varscan2
- TTN | c.49464G>A p.W16488* (on ENST00000591111; = p.W9064* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV59924304; called by muse, mutect2, varscan2
- UBASH3B | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs949908246, COSV52491433; called by muse, mutect2, varscan2
- UGT2B15 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | catalogued as rs1371039880, COSV57733306; called by muse, mutect2
- UGT2B17 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as rs1356849503, COSV58501014; called by muse, mutect2
- USH2A | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1487010011, COSV56337534; called by muse, mutect2, varscan2
- YEATS2 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs866031237, COSV59362713; called by muse, mutect2, varscan2
- ZBTB7C | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1161916940, COSV59687889, COSV59690092; called by muse, mutect2, varscan2
- ZDBF2 | c.4553A>T p.K1518I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV65622769; called by muse, mutect2, varscan2
- ZNF229 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs748667361, COSV52160312; called by muse, mutect2, varscan2
- ZNF721 | c.859C>T p.H287Y (on ENST00000338977; = p.H299Y on NM_133474.4) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59090146; called by muse, mutect2, varscan2
- ZNF831 | c.4178G>A p.R1393Q | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs753837433, COSV64037136; called by muse, mutect2, varscan2
- ANKRD11 | c.5042del p.A1681Efs*5 | Frame Shift Del (DEL) | VAF 59/96 reads (61%) | called by mutect2, pindel, varscan2
- ANKRD9 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); called by muse, mutect2
- COL4A6 | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 168/204 reads (82%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GGA3 | c.728G>A p.G243E (on ENST00000537686 / NM_138619.4; = p.G210E on NM_014001.5) | Missense Mutation (SNP) | VAF 125/228 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GLDN | c.296_316delinsC p.E99Afs*5 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | called by pindel, varscan2*
- KANSL1 | c.2516_2537del p.S839Nfs*5 (on ENST00000574590 / NM_001193465.2; = p.S839Nfs*6 on NM_015443.4) | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | called by mutect2, pindel, varscan2
- OR8G2P | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- POLD3 | c.979C>G p.P327A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- THSD1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ABCA2 | c.2382C>T p.S794= (on ENST00000614293; = p.S764= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/37 reads (100%) | catalogued as rs375003196; called by muse, mutect2, varscan2
- ADAMTS18 | c.1833C>T p.F611= | Silent (SNP) | VAF 79/93 reads (85%) | catalogued as COSV51400235; called by muse, mutect2, varscan2
- AIFM2 | c.165C>T p.A55= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV57158842; called by muse, mutect2, varscan2
- ALAS1 | c.687C>T p.F229= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV59627064; called by muse, mutect2, varscan2
- APLP2 | c.2259C>T p.P753= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV53839379; called by muse, mutect2, varscan2
- ATF6B | c.921C>T p.I307= | Silent (SNP) | VAF 107/346 reads (31%) | catalogued as rs758672739, COSV64351442; called by muse, mutect2, varscan2
- C12orf50 | c.1035C>T p.V345= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs368194114; called by muse, mutect2, varscan2
- C1D | c.72C>G p.S24= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV63412996, COSV63413506; called by muse, mutect2, varscan2
- CACNA1A | c.1842C>T p.I614= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs374686479; called by muse, mutect2, varscan2
- CAMSAP2 | c.4266C>A p.I1422= (on ENST00000236925 / NM_001297707.2; = p.I1411= on NM_203459.3) | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV52667565; called by muse, mutect2, varscan2
- CAND2 | c.2712C>T p.I904= (on ENST00000456430 / NM_001162499.2; = p.I811= on NM_012298.3) | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs374047348; called by muse, mutect2, varscan2
- CHRNA10 | c.348C>T p.I116= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1270107240, COSV51703205; called by muse, mutect2, varscan2
- CLASP2 | c.3823C>T p.L1275= (on ENST00000359576; = p.L1274= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV56277605; called by muse, mutect2, varscan2
- COL4A6 | c.1938C>T p.G646= | Silent (SNP) | VAF 166/203 reads (82%) | catalogued as rs769443240; called by muse, mutect2, varscan2
- CPZ | c.222G>A p.E74= (on ENST00000360986 / NM_001014447.3; = p.E63= on NM_003652.3) | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV59921917; called by muse, mutect2, varscan2
- DCAF12L2 | c.618C>T p.T206= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs1291925445, COSV63580649, COSV63582462; called by muse, mutect2, varscan2
- DHRS3 | c.420C>T p.L140= | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as rs776634835, COSV66107726; called by muse, mutect2, varscan2
- DHX35 | c.1707C>T p.F569= | Silent (SNP) | VAF 73/164 reads (45%) | catalogued as COSV52668201, COSV52671914; called by muse, mutect2, varscan2
- DNAH1 | c.1155G>A p.T385= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs141835525, COSV101324668, COSV70227020; called by muse, mutect2, varscan2
- DNAH3 | c.9030C>T p.G3010= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs754879095, COSV54501899; called by muse, mutect2, varscan2
- DNAH9 | c.6411G>A p.L2137= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs761980508, COSV52338836; called by muse, mutect2, varscan2
- DNMT1 | c.4344C>T p.D1448= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs200416276; ClinVar: likely benign; called by muse, varscan2
- EDAR | c.606C>T p.I202= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs201950451, COSV51500510; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESYT3 | c.900C>T p.R300= | Silent (SNP) | VAF 91/218 reads (42%) | catalogued as COSV56679793; called by muse, varscan2
- FBXO10 | c.2688C>T p.F896= | Silent (SNP) | VAF 51/61 reads (84%) | catalogued as COSV52831767, COSV52831928; called by muse, mutect2, varscan2
- GRID2 | c.798C>T p.N266= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs755074343, COSV56180903; called by muse, mutect2, varscan2
- GSDMB | c.354C>T p.I118= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs1262947084, COSV58779627, COSV58779895; called by muse, mutect2, varscan2
- IL1F10 | c.384C>T p.P128= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100520250, COSV61750365; called by muse, mutect2, varscan2
- IRGQ | c.261G>A p.G87= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV60670288; called by muse, mutect2, varscan2
- KIAA1217 | c.4926G>A p.E1642= | Silent (SNP) | VAF 23/26 reads (88%) | catalogued as COSV56813422; called by muse, mutect2, varscan2
- MBD4 | c.1404G>A p.R468= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV51444105; called by muse, mutect2, varscan2
- MTA2 | c.93C>T p.N31= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1468208793, COSV53870879; called by muse, mutect2, varscan2
- MTNR1B | c.834C>T p.P278= | Silent (SNP) | VAF 164/399 reads (41%) | catalogued as COSV57065684; called by muse, mutect2, varscan2
- MUC16 | c.41337G>A p.S13779= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs368301608; called by muse, mutect2, varscan2
- MUC16 | c.28929A>G p.E9643= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV67451338; called by muse, mutect2
- MUC16 | c.3081G>A p.T1027= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as rs750106551, COSV101200016, COSV67451353; called by muse, mutect2, varscan2
- MUC17 | c.8811C>T p.T2937= | Silent (SNP) | VAF 94/111 reads (85%) | catalogued as rs530486985, COSV60282250; called by muse, mutect2, varscan2
- MYBPC2 | c.2142C>T p.F714= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs371647573; called by muse, mutect2, varscan2
- NLRP2 | c.2997G>A p.V999= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as rs866152757, COSV54752974; called by muse, mutect2, varscan2
- OR11L1 | c.960C>T p.F320= | Silent (SNP) | VAF 47/49 reads (96%) | catalogued as COSV63313830; called by muse, mutect2, varscan2
- OR2G6 | c.597C>T p.L199= | Silent (SNP) | VAF 54/62 reads (87%) | catalogued as COSV100598337, COSV58573901; called by muse, mutect2, varscan2
- OR4A16 | c.33C>T p.V11= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV59042169; called by muse, mutect2, varscan2
- OR4A16 | c.252C>T p.L84= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as COSV59042178; called by muse, mutect2, varscan2
- OR4X1 | c.141C>T p.I47= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV60722364; called by muse, mutect2, varscan2
- PIK3C2A | c.3103C>T p.L1035= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56401112; called by muse, mutect2, varscan2
- PLCH1 | c.1776G>A p.R592= (on ENST00000340059 / NM_001130960.2; = p.R604= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58188626; called by muse, mutect2, varscan2
- PLPP7 | c.36C>T p.D12= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV64835846; called by muse, mutect2, varscan2
- RBM5 | c.417C>T p.S139= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV61736745; called by muse, mutect2, varscan2
- RFFL | c.783C>A p.I261= | Silent (SNP) | VAF 62/149 reads (42%) | catalogued as COSV52070945; called by muse, mutect2, varscan2
- RHBDF1 | c.1215C>T p.F405= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV51953859; called by muse, mutect2, varscan2
- SCD | c.810C>T p.L270= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as rs1334444523, COSV64852892; called by muse, mutect2, varscan2
- SCN7A | c.726C>T p.I242= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs541727773, COSV69269629; called by muse, mutect2
- SCN9A | c.4722C>T p.F1574= (on ENST00000303354; = p.F1563= on NM_002977.3) | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV57602916; called by muse, mutect2, varscan2
- SIN3B | c.1884C>T p.I628= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs141051908; called by muse, mutect2, varscan2
- SLC22A11 | c.471C>T p.S157= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV57252190; called by muse, mutect2, varscan2
- SLFN11 | c.654C>T p.F218= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs755615026, COSV57697881; called by muse, mutect2, varscan2
- SORCS2 | c.2634G>A p.L878= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1488428514, COSV61164559; called by muse, mutect2, varscan2
- SRRM4 | c.168G>A p.Q56= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV57410509; called by muse, mutect2, varscan2
- STYXL2 | c.1101G>A p.Q367= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV54802854, COSV54809500; called by muse, mutect2, varscan2
- TENM4 | c.3231C>T p.I1077= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53612896; called by muse, mutect2, varscan2
- TKTL2 | c.1800G>A p.G600= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs1372107705, COSV54917848; called by muse, mutect2, varscan2
- TRAV30 | c.15G>A p.L5= | Silent (SNP) | VAF 98/212 reads (46%) | called by muse, mutect2, varscan2
- TRRAP | c.5244G>A p.Q1748= (on ENST00000359863 / NM_001244580.1; = p.Q1730= on NM_003496.3) | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV62840662; called by muse, mutect2, varscan2
- XIRP2 | c.9732C>T p.F3244= (on ENST00000628543; = p.F3419= on NM_152381.6) | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54687178; called by muse, mutect2, varscan2
- ZNF180 | c.1194C>T p.S398= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV55420089; called by muse, mutect2, varscan2
- ZNFX1 | c.4464G>A p.R1488= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV65594920; called by muse, mutect2, varscan2
- CFAP47 | c.5536-635G>A | Intron (SNP) | VAF 43/56 reads (77%) | catalogued as COSV100545577, COSV57971805; called by muse, mutect2, varscan2
- HNMT | c.137+2485T>G | Intron (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-125G>A | Intron (SNP) | VAF 32/38 reads (84%) | called by muse, mutect2, varscan2
- MIR557 | n.2G>A | RNA (SNP) | VAF 258/268 reads (96%) | catalogued as rs1444669576; called by muse, mutect2, varscan2
- SFTA3 | n.924C>T | RNA (SNP) | VAF 61/140 reads (44%) | catalogued as rs267603984, COSV69488913; called by muse, mutect2, varscan2
- SNORD114-29 | n.3G>A | RNA (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
